Somatic mutation profile of tumor specimen MMRF_1550_1_BM_CD138pos (aliquot MMRF_1550_1_BM_CD138pos_T1_KBS5U_L03478) from MMRF case MMRF_1550, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.8 years (26,235 days).
Specimen MMRF_1550_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f837e69d-f3fb-4688-9152-fabc33a6899a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1550_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1550_1_PB_Whole_C2_KBS5U_L03490; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57148f7d-a1ff-4e42-a44f-0246db1dfdc3

The open-access MAF lists 113 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 32, Silent 14, Intron 10, Splice Site 3, 5'Flank 3, 5'UTR 2, 3'Flank 2, Frame Shift Ins 1, RNA 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 37/75 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARFGEF3 | c.5909G>A p.R1970Q | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as rs1157091678; called by muse, mutect2, varscan2
- CYP4F12 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 120/330 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs773893383, COSV61172924; called by muse, mutect2, varscan2
- FIGN | c.799dup p.A267Gfs*100 | Frame Shift Ins (INS) | VAF 34/80 reads (43%) | catalogued as rs755527396; called by mutect2, varscan2
- FTMT | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100360436, COSV58419583; called by muse, mutect2, varscan2
- GRID2 | c.2948C>T p.S983L | Missense Mutation (SNP) | VAF 124/275 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.879); catalogued as COSV56181959; called by muse, mutect2, varscan2
- IGHV2-70 | c.283T>A p.S95T | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs568191048; called by muse, varscan2
- IGHV2-70 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373749501; called by muse, varscan2
- IGHV2-70 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376458450; called by muse, varscan2
- IGHV2-70 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs370193821; called by muse, varscan2
- KRTAP12-3 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs782699604; called by muse, mutect2, varscan2
- KRTAP13-2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 342/529 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as rs773268499; called by muse, varscan2
- LRRC30 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs1178690025, COSV67301390; called by muse, mutect2, varscan2
- MUC4 | c.13291G>A p.E4431K (on ENST00000463781 / NM_018406.7; = p.E195K on NM_004532.6) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1462978621, COSV57805454; called by muse, mutect2, varscan2
- MYH2 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146229690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NXPE4 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1004302011; called by muse, mutect2, varscan2
- PCDH10 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52091739; called by muse, mutect2, varscan2
- RABGAP1L | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52299313; called by muse, mutect2, varscan2
- SCN7A | c.3501C>G p.I1167M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs562561697; called by muse, mutect2, varscan2
- TMEM151B | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs774769249, COSV101441999; called by muse, mutect2
- WDR62 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1349554131; called by muse, mutect2, varscan2
- ADAMTS16 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.10254A>T p.R3418S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APEX1 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- ATL3 | c.561+2_561+15del p.X187_splice | Splice Site (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel
- DBH | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ECPAS | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHMT1 | c.1607C>G p.A536G | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- FAM20C | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GARNL3 | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- GLDN | c.1615C>T p.L539F | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HYLS1 | c.81T>A p.F27L | Missense Mutation (SNP) | VAF 214/303 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- IGHV1-69D | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 78/134 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, varscan2
- IL32 | c.149A>T p.D50V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KCNJ6 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 67/110 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCORL | c.4577C>G p.A1526G | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAPK4 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO1B | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- NTF3 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OSBPL6 | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCNT | c.3803_3807delinsT p.D1268Vfs*48 | Frame Shift Del (DEL) | VAF 52/134 reads (39%) | called by pindel, varscan2*
- PCP2 | c.52-1G>A p.X18_splice | Splice Site (SNP) | VAF 139/224 reads (62%) | called by muse, mutect2, varscan2
- RERGL | c.521T>G p.I174R | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHOC | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- SLC12A2 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC22A6 | c.473+1G>C p.X158_splice | Splice Site (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- TCP10L2 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.019); called by mutect2, varscan2
- USP49 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- ZNF789 | c.266-6G>C | Splice Region (SNP) | VAF 33/104 reads (32%) | called by muse, mutect2, varscan2
- ASXL3 | c.459C>T p.T153= | Silent (SNP) | VAF 75/201 reads (37%) | catalogued as rs761050325; called by muse, mutect2, varscan2
- CPXM1 | c.1167C>A p.T389= | Silent (SNP) | VAF 68/138 reads (49%) | called by muse, mutect2, varscan2
- HLA-DQB1 | c.123C>T p.F41= | Silent (SNP) | VAF 34/44 reads (77%) | catalogued as rs111588946; called by muse, mutect2
- IGDCC4 | c.2274G>A p.A758= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs745801357, COSV61536726; called by muse, mutect2, varscan2
- IGHV2-70 | c.198G>A p.L66= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs562646171; called by muse, varscan2
- IGHV2-70 | c.30A>T p.L10= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs781292434; called by muse, varscan2
- IGKJ4 | c.21C>A p.T7= | Silent (SNP) | VAF 22/22 reads (100%) | catalogued as rs545670469; called by muse, varscan2
- KIAA1614 | c.783C>T p.S261= | Silent (SNP) | VAF 63/181 reads (35%) | catalogued as rs776354353, COSV62552750; called by muse, mutect2, varscan2
- NWD1 | c.1551G>A p.P517= | Silent (SNP) | VAF 63/92 reads (68%) | catalogued as rs148902093; called by muse, mutect2, varscan2
- PNLDC1 | c.1503C>T p.V501= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as rs1251535587, COSV99277979; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1287A>G p.Q429= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs1421354519, COSV52964769; called by muse, mutect2, varscan2
- SHISA6 | c.534C>G p.V178= | Silent (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- TBL2 | c.42G>C p.V14= | Silent (SNP) | VAF 38/61 reads (62%) | called by muse, mutect2, varscan2
- UNC80 | c.6552C>T p.D2184= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs377594006, COSV104380862; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABRAXAS2 | c.*800G>C | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- ACTR3 | c.*4631T>C | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- AL358334.1 | n.29-7422T>C | Intron (SNP) | VAF 147/287 reads (51%) | catalogued as rs749398534; called by muse, mutect2, varscan2
- ANKRD22 | c.*756dup | 3'UTR (INS) | VAF 37/75 reads (49%) | catalogued as rs1191896834; called by mutect2, varscan2
- BCL7A | chr12:122021473 del C | 5'Flank (DEL) | VAF 27/62 reads (44%) | called by mutect2, pindel, varscan2
- BMPR2 | c.*1515dup | 3'UTR (INS) | VAF 33/101 reads (33%) | catalogued as rs544291874; called by mutect2, varscan2
- BSND | c.*823G>A | 3'UTR (SNP) | VAF 56/128 reads (44%) | catalogued as rs1388831998; called by muse, mutect2
- BTF3 | c.201+29T>G | Intron (SNP) | VAF 14/39 reads (36%) | catalogued as rs777899021, COSV60063114, COSV60063131; called by muse, mutect2, varscan2
- C1D | c.*34T>A | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by mutect2, varscan2
- C4orf46 | c.*1065A>G | 3'UTR (SNP) | VAF 38/87 reads (44%) | catalogued as rs1198530556; called by muse, mutect2, varscan2
- CALN1 | c.*822C>A | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- CDH7 | chr18:65884738 C>A | 3'Flank (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- CHMP1B | c.*547C>T | 3'UTR (SNP) | VAF 60/191 reads (31%) | called by muse, mutect2, varscan2
- CMC1 | c.*4109T>C | 3'UTR (SNP) | VAF 61/114 reads (54%) | called by muse, mutect2, varscan2
- CNOT7 | c.-117G>T | 5'UTR (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- COL6A2 | c.2461+2575G>A | Intron (SNP) | VAF 43/152 reads (28%) | catalogued as rs1018849101, COSV56020095; called by muse, mutect2, varscan2
- EEF1B2 | c.203+9A>T | Intron (SNP) | VAF 171/356 reads (48%) | called by muse, mutect2, varscan2
- EGFR | c.*5056C>T | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- FAM120A | c.*529T>C | 3'UTR (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- FOXRED1 | c.*364del | 3'UTR (DEL) | VAF 46/155 reads (30%) | called by mutect2, pindel, varscan2
- GPR179 | chr17:38343911 C>T | 5'Flank (SNP) | VAF 8/19 reads (42%) | catalogued as rs1004371846; called by muse, mutect2, varscan2
- KHSRP | c.*483T>G | 3'UTR (SNP) | VAF 24/30 reads (80%) | called by muse, mutect2, varscan2
- KRT4 | c.*332C>A | 3'UTR (SNP) | VAF 27/47 reads (57%) | called by muse, mutect2, varscan2
- LHX6 | c.*54C>T | 3'UTR (SNP) | VAF 19/64 reads (30%) | catalogued as rs750075092, COSV61344367; called by muse, mutect2, varscan2
- LRPAP1 | c.*1507T>C | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- MCF2L | c.369-389G>A | Intron (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- MIR365B | chr17:31571275 A>G | 5'Flank (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- MON2 | chr12:62602674 C>G | 3'Flank (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- OR6J1 | c.*191T>G | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, varscan2
- P2RX4 | c.747+40G>A | Intron (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- PDZD2 | c.*2573G>A | 3'UTR (SNP) | VAF 43/136 reads (32%) | called by muse, mutect2, varscan2
- PSMB9 | c.532+108C>T | Intron (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- RAB1B | c.*942C>G | 3'UTR (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- RABL2B | c.*227G>A | 3'UTR (SNP) | VAF 124/326 reads (38%) | called by muse, mutect2, varscan2
- RASSF1 | c.251-104A>C | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- RC3H2 | c.1325+3179T>A | Intron (SNP) | VAF 43/222 reads (19%) | called by muse, mutect2, varscan2
- RNF113A | c.*61G>A | 3'UTR (SNP) | VAF 93/94 reads (99%) | called by muse, mutect2, varscan2
- RPIA | c.*334T>C | 3'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- RTL6 | c.*2575C>T | 3'UTR (SNP) | VAF 63/141 reads (45%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.*156G>C | 3'UTR (SNP) | VAF 49/157 reads (31%) | called by muse, mutect2, varscan2
- STAT5B | c.*172C>T | 3'UTR (SNP) | VAF 4/80 reads (5%) | catalogued as rs1049671730; called by muse, mutect2
- STX3 | c.*24C>G | 3'UTR (SNP) | VAF 102/329 reads (31%) | called by muse, mutect2, varscan2
- SUMF1 | c.*827C>T | 3'UTR (SNP) | VAF 20/45 reads (44%) | catalogued as rs1185645694; called by muse, mutect2, varscan2
- SYAP1 | c.*3971T>G | 3'UTR (SNP) | VAF 34/35 reads (97%) | called by muse, mutect2, varscan2
- SYBU | c.*523A>G | 3'UTR (SNP) | VAF 59/126 reads (47%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2634T>C | RNA (SNP) | VAF 14/140 reads (10%) | catalogued as rs745371959; called by mutect2, varscan2
- THG1L | c.*378C>T | 3'UTR (SNP) | VAF 40/75 reads (53%) | catalogued as rs747502165; called by muse, mutect2, varscan2
- TMEM196 | c.-274C>T | 5'UTR (SNP) | VAF 37/76 reads (49%) | catalogued as rs933683237; called by muse, mutect2, varscan2
- TNS1 | c.4331-24C>A | Intron (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- ZNF717 | c.*508G>A | 3'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as rs1283269444; called by muse, mutect2, varscan2
